Somatic mutation profile of tumor specimen MP2PRT-PATPDL-TMP1-A (aliquot MP2PRT-PATPDL-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATPDL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,548 days).
Specimen MP2PRT-PATPDL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03c24b81-5cb7-4883-b678-ee606c4b1a4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATPDL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATPDL-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9c2c5f0-305e-4f80-81c2-4e604687ab77

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 15, Silent 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.10700C>T p.T3567M | Missense Mutation (SNP) | VAF 179/395 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs368278927, CM077505, COSV51940199; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 20/395 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 125/372 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARMCX2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 32/726 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs1556060599; called by muse, mutect2
- CYP2D6 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 36/870 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs377488485; called by muse, mutect2
- FLRT3 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 182/414 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54009663; called by muse, mutect2, varscan2
- MAP7 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 26/522 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63421921; called by muse, mutect2
- ARMH2 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 109/406 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- DOCK5 | c.3002T>C p.V1001A | Missense Mutation (SNP) | VAF 36/542 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- ELOVL4 | c.40G>T p.V14L | Missense Mutation (SNP) | VAF 193/384 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- EYS | c.2399G>T p.G800V | Missense Mutation (SNP) | VAF 81/281 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGHV3-53 | c.347_348insGCTCGCGAG | In Frame Ins (INS) | VAF 23/44 reads (52%) | called by mutect2, pindel
- KMT2D | c.7750A>T p.T2584S | Missense Mutation (SNP) | VAF 235/498 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- MOGAT1 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 61/294 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- OR5P2 | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- TRPC6 | c.2145G>T p.M715I | Missense Mutation (SNP) | VAF 145/311 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PTGS2 | c.576G>A p.T192= | Silent (SNP) | VAF 170/417 reads (41%) | catalogued as rs200316914, COSV66571277; called by muse, mutect2, varscan2
- SRSF4 | c.699G>C p.R233= | Silent (SNP) | VAF 166/394 reads (42%) | called by muse, mutect2, varscan2
- TMEM249 | c.333C>T p.R111= | Silent (SNP) | VAF 270/602 reads (45%) | called by muse, mutect2, varscan2
